Surgical pathology report (de-identified scan), TCGA case TCGA-50-5051, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5051-01A (Primary Tumor).

FINAL DIAGNOSIS:**SUMMARY STATEMENT:**

The left upper lobectomy demonstrates a moderately differentiated adenocarcinoma, 2.0 cm in diameter, associated with metastases to the level 5 lymph nodes and accompanied by visceral pleural invasion. All margins free. Pathologic stage; T2 N2 Mx.

**PART 1: LUNG, LEFT UPPER LOBE, BRONCHOSCOPIC BIOPSY –
FRAGMENTS OF BRONCHIAL MUCOSA WITH NO SIGNIFICANT ABNORMALITY.**

**PART 2: LYMPH NODE, LEVEL 5 LYMPH NODES, BIOPSY –
TWO OF THREE LYMPH NODE FRAGMENTS WITH METASTATIC ADENOCARCINOMA (2/3).**

**PART 3: LYMPH NODE, LEVEL 12 LYMPH NODE, BIOPSY –
SOLITARY FRAGMENT OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.**

**PART 4: LYMPH NODE, LEVEL 11 LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.**

**PART 5: BONE, "RIB", RESECTION –
SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.**

PART 6: LUNG, LEFT UPPER LOBE, LOBECTOMY –

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH CLEAR CELL, SOLID, MUCINOUS AND FETAL ADENOCARCINOMA-LIKE AREAS ASSOCIATED WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION, DIAMETER 2.0 CM. ALL MARGIN FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T2 N2 MX.**
- B. SOLITARY HILAR LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.**
- C. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.**
- D. MULTIFOCAL ATYPICAL ADENOMATOUS HYPERPLASIA.**
- E. PULMONARY ARTERIES WITH MARKED MYOINTIMAL THICKENING.**

Source: NCI Genomic Data Commons file 09c81ca2-a53d-4073-b3c1-003b97d5f260 (TCGA-50-5051.FF5F5187-C4DA-482C-B6FE-CBDE5C820A80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).